Somatic mutation profile of tumor specimen MP2PRT-PATVVI-TMP1-A (aliquot MP2PRT-PATVVI-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PATVVI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,086 days).
Specimen MP2PRT-PATVVI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 207101b0-1506-4f02-9fea-78bf5e7fdd90.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATVVI-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATVVI-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/85180508-3a28-457f-a7a1-45fca8757bf5

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 13, Silent 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 114/315 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- BIRC6 | c.13151A>T p.D4384V | Missense Mutation (SNP) | VAF 93/229 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV70199883; called by muse, mutect2, varscan2
- CNTN5 | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 125/251 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1215380044, COSV54283284, COSV54294122; called by muse, mutect2, varscan2
- DGAT2L6 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 192/872 reads (22%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.477); catalogued as rs1289127200, COSV60717354; called by muse, mutect2, varscan2
- DPF3 | c.250C>T p.R84* | Nonsense Mutation (SNP) | VAF 148/547 reads (27%) | catalogued as rs764426480, COSV100818531, COSV100818605; called by muse, mutect2, varscan2
- OTOF | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 114/251 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as rs147435768; called by muse, mutect2, varscan2
- PCDHGA4 | c.1973G>A p.R658H | Missense Mutation (SNP) | VAF 198/409 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.96); catalogued as COSV104390582; called by muse, mutect2, varscan2
- SERINC4 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 232/494 reads (47%) | SIFT tolerated (0.93); PolyPhen benign (0.009); catalogued as rs1247541870; called by muse, mutect2, varscan2
- SULT1E1 | c.104C>A p.A35E | Missense Mutation (SNP) | VAF 104/383 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56946545; called by muse, mutect2, varscan2
- TRPM3 | c.442G>A p.G148R (on ENST00000357533 / NM_001366142.2; = p.G117R on NM_001007471.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/378 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV62471678, COSV62474705; called by muse, mutect2
- ZP2 | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 156/342 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs535760240, COSV54816524; called by muse, mutect2, varscan2
- MRGPRG | c.373C>T p.L125F | Missense Mutation (SNP) | VAF 287/663 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- MYH14 | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 150/315 reads (48%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- UBR1 | c.4428C>G p.F1476L | Missense Mutation (SNP) | VAF 119/253 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD22 | c.207G>A p.S69= | Silent (SNP) | VAF 184/347 reads (53%) | catalogued as rs747204167, COSV99323449; called by muse, mutect2, varscan2
- RIPK4 | c.2454C>T p.G818= (on ENST00000352483; = p.G770= on NM_020639.3) | Silent (SNP) | VAF 233/1164 reads (20%) | catalogued as rs767725466, COSV100205401; called by muse, mutect2
- YAE1 | c.642C>A p.G214= | Silent (SNP) | VAF 92/175 reads (53%) | called by muse, mutect2, varscan2
